Somatic mutation profile of tumor specimen TCGA-GS-A9U4-01A (aliquot TCGA-GS-A9U4-01A-11D-A38X-10) from TCGA case TCGA-GS-A9U4, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 27.6 years (10,075 days).
Specimen TCGA-GS-A9U4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6521d692-3b2b-4d69-80ee-71497a8778f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9U4-10A (Blood Derived Normal), aliquot TCGA-GS-A9U4-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afa05eec-d352-4a96-bf64-7164b93fe9e0

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.2638G>A p.V880M (on ENST00000372530 / NM_001198934.2; = p.V852M on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs534141558, COSV55086961; called by mutect2, varscan2
- ATP6V1H | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 10/304 reads (3%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV100778723; called by muse, mutect2
- CAMTA1 | c.3190C>G p.R1064G | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100349403, COSV100351536; called by muse, mutect2
- CDH3 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50556624; called by muse, mutect2, varscan2
- CNGB1 | c.3521C>T p.T1174M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs758143647, COSV99204831; called by muse, mutect2, varscan2
- DLGAP3 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.031); catalogued as rs1409887611, COSV99332942; called by muse, mutect2, varscan2
- EBF3 | c.1175G>A p.G392E (on ENST00000355311 / NM_001375392.1; = p.G383E on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100799451; called by muse, mutect2
- GRIN2A | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1555491654, COSV100410478; called by muse, mutect2
- GRINA | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as rs560551768, COSV57297391; called by muse, mutect2
- IGKV1-5 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as rs373427862; called by muse, mutect2, varscan2
- ITPR3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778958478, COSV65414828; called by muse, mutect2, varscan2
- KIAA1549L | c.3013G>A p.V1005M (on ENST00000321505; = p.V1302M on NM_012194.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs369439478; called by muse, mutect2, varscan2
- KTN1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as rs1192477049, COSV101254930, COSV68023629; called by muse, mutect2, varscan2
- MAP1B | c.6698A>C p.K2233T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99702691; called by muse, mutect2, varscan2
- MCM3AP | c.3017G>A p.G1006D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as COSV99387228; called by muse, mutect2
- MED12 | c.4394G>A p.R1465H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100379952, COSV61340856; called by muse, mutect2
- MYH7B | c.5390G>A p.R1797Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.812); catalogued as rs769064302, COSV99328678; called by mutect2, varscan2
- NEK1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1041766237, COSV101455750; called by muse, mutect2, varscan2
- PKN2 | c.1609C>G p.Q537E | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.022); catalogued as COSV100281681; called by muse, mutect2
- SMARCD3 | c.1136C>T p.T379M (on ENST00000262188 / NM_001003801.2; = p.T366M on NM_003078.4) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as rs772092145; called by mutect2, varscan2
- TET1 | c.5069G>A p.R1690Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs1333809107, COSV101018576; called by muse, mutect2
- TRPM3 | c.2588G>C p.G863A (on ENST00000357533 / NM_001366142.2; = p.G706A on NM_020952.6) | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100677934; called by muse, mutect2
- UBE2R2 | c.293A>T p.H98L | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99602353; called by muse, mutect2
- IGKV1D-13 | c.351del p.P117del | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by pindel*, varscan2
- GAL3ST4 | c.1419C>G p.T473= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100385577; called by muse, mutect2
- HS3ST6 | c.666C>T p.A222= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as rs371489616, COSV53535356; called by mutect2, varscan2
- MYH10 | c.861G>A p.L287= | Silent (SNP) | VAF 15/154 reads (10%) | catalogued as COSV99345821; called by muse, mutect2, varscan2
- MYH11 | c.4008G>A p.T1336= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs749476388, COSV100259622; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAB40A | c.234C>T p.T78= | Silent (SNP) | VAF 22/270 reads (8%) | catalogued as COSV100420981; called by muse, mutect2
- RS1 | c.309C>T p.L103= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1479982189, COSV101183835; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1158C>T p.T386= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV100836147; called by muse, mutect2, varscan2
- TRPM3 | c.2589C>A p.G863= (on ENST00000357533 / NM_001366142.2; = p.G706= on NM_020952.6) | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV100677932; called by muse, mutect2
